Surgical pathology report (de-identified scan), TCGA case TCGA-55-7570, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7570-01A (Primary Tumor).

[page 1 of 3]
*** Final Report ***

Clinical History

Right lung upper lobe nodule

Specimen

- #1 Right upper lobe wedge biopsy
- #2 Completion of right upper lobectomy-right upper lobe, freeze bronchial margins
- #3 Level 7
- #4 Level 10

Gross Examination

#1 Right lung, upper lobe, wedge biopsy: Received in the fresh state is a wedge shaped portion of lung weighing 57.5 grams and roughly 7.5 x 5.5 x 2.5 cm. Within the tissue is a well circumscribed, nonencapsulated tumor roughly 2.0 x 2.0 x 1.3 cm. The tumor grossly extends to within 0.2 cm of the surgical resection margin. The tumor is 0.2 cm deep to the pleural surface. The surrounding lung tissue is soft and dark red. A portion of the tumor to include the surgical resection margin is submitted for frozen section evaluation. With the expressed written consent of the patient, a portion of the tumor is triaged for the Cancer Genome Atlas Project. Additional tissue is sampled in six cassettes for permanent section. Block Summary: "A","B", tumor with closest surgical margin; "C", subpleural tumor; "D","E", tumor; "F", grossly normal lung tissue. [REDACTED]

#2 Received fresh labeled completion of right upper lobectomy, right upper lobe, is a 352.5 gram, 21.0 x 11.0 x up to 3.5 cm lobe of lung. The bronchial margin is submitted for Frozen Section as "2FS". Extending in either direction from the stapled bronchial margin, is a 19.0 cm long staple line. On the opposite surface there is a 13.0 cm long staple line. The pleura is dark red purple, smooth and glistening. The tissue is serially sectioned to demonstrate a dark red brown, soft spongy parenchyma, with no discrete mass or lesion identified. There are two dark grey peribronchial lymph node candidates, 0.7 and 1.0 cm in greatest dimension. Eleven representative sections are submitted in five: "A-E". Block summary: "A", vascular margins and bronchial tissue just deep to bronchial margin Frozen Section; "B", two individual peribronchial lymph node candidates; "C,D", parenchyma beneath the staple line opposite the bronchus; "E", uninvolved parenchyma away from the staple line.

[REDACTED]

[page 2 of 3]
*** Final Report ***

#3 Labeled Level 7, is a 0.6 x 0.4 x 0.2 cm irregular fragment of dark grey soft tissue, entirely submitted in one cassette.

#4 Labeled Level 10, is a 1.2 x 0.8 x 0.4 cm aggregate of two irregular fragments of dark red soft tissue, entirely submitted in one cassette.

Frozen Section Diagnosis

#1 RIGHT LUNG, UPPER LOBE; WEDGE BIOPSY (1 FS): NON-SMALL CELL CARCINOMA, FAVOR SQUAMOUS CARCINOMA. TUMOR GROSSLY EXTENDS TO WITHIN 2 MM OF SURGICAL RESECTION MARGIN.

#2 RIGHT LUNG, UPPER LOBE BRONCHIAL MARGIN (1 FS): NEGATIVE.

Microscopic Examination

#1-#4 Microscopic examination performed.

Comment

The lesional cells have the following immunophenotypic profile (immunoperoxidase technique): CK5/6 (-), CK7 (focal +), p63 (-), and TTF-1 (rare +). The immunophenotypic findings support the interpretation of adenocarcinoma.

Final Diagnosis

- #1 RIGHT LUNG, UPPER LOBE; WEDGE BIOPSY: POORLY DIFFERENTIATED ADENOCARCINOMA, SOLID TYPE.
TUMOR SIZE: 2.0 X 2.0 X 1.3 CM.
SURGICAL MARGIN STATUS: TUMOR EXTENDS TO WITHIN 0.2 CM OF SURGICAL MARGIN.
PLEURAL SURFACE STATUS: NEGATIVE FOR CARCINOMA.
LYMPHOVASCULAR SPACE INVASION: ABSENT.
- #2 RIGHT LUNG, UPPER LOBE; EXCISION: BENIGN LUNG TISSUE (NEGATIVE FOR RESIDUAL CARCINOMA).
BRONCHIAL MARGIN: FREE.
PERIBRONCHIAL LYMPH NODES: TWO LYMPH NODES, NO TUMOR PRESENT.
- #3 MEDIASTINAL (LEVEL 7) LYMPH NODE BIOPSY: BENIGN LYMPH NODE.
- #4 MEDIASTINAL (LEVEL 10) LYMPH NODE BIOPSY: BENIGN LYMPH NODE.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT1a pN0.

Ordering Provider

[page 3 of 3]
[REDACTED]

Ordering Physician: [REDACTED]

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file b76b4afc-c847-4752-a23a-b332bc2061c8 (TCGA-55-7570.95CB32D6-2999-44EB-A93F-31AA65A6C51C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).